Somatic mutation profile of cancer-model specimen HCM-BROD-0830-C71-85R (Mixed Adherent Suspension, passage 10; aliquot HCM-BROD-0830-C71-85R-01D-A85K-36), derived from the recurrence tumor of HCMI case HCM-BROD-0830-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,323 days).
Specimen HCM-BROD-0830-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4ff1a78-2804-4396-9b26-324dc59b801b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0830-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0830-C71-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda2b425-51e2-4a88-86ef-4c8761779514

The open-access MAF lists 152 somatic variants for this specimen: 122 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 27, Frame Shift Del 19, Nonsense Mutation 6, In Frame Del 3, Intron 3, Splice Region 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 269/269 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ADCY1 | c.1020G>A p.T340= | Splice Region (SNP) | VAF 78/346 reads (23%) | catalogued as rs775492975, COSV99812760; called by muse, mutect2, varscan2
- ANKRD11 | c.4925C>T p.P1642L | Missense Mutation (SNP) | VAF 117/355 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs753598147; called by muse, mutect2, varscan2
- AP2B1 | c.766del p.V256Cfs*5 | Frame Shift Del (DEL) | VAF 98/360 reads (27%) | catalogued as COSV51998308; called by mutect2, pindel, varscan2
- ARHGEF5 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 86/530 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs755891405; called by muse, mutect2, varscan2
- ASPM | c.5008G>A p.V1670I | Missense Mutation (SNP) | VAF 75/287 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs765920262, COSV99661494; called by muse, mutect2, varscan2
- ATP4A | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 321/774 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370650252; called by muse, mutect2, varscan2
- B3GALT6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 193/748 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1267101770; called by muse, mutect2, varscan2
- C1orf141 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.349); catalogued as rs776456150; called by muse, mutect2, varscan2
- CCBE1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768229052, COSV101232777, COSV67949152; called by muse, mutect2, varscan2
- CDCA5 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 160/301 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs774757594; called by muse, mutect2, varscan2
- CHPF | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 266/408 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as rs1388942317; called by muse, mutect2, varscan2
- CLPS | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140627661; called by muse, mutect2, varscan2
- COL21A1 | c.2042C>A p.S681Y | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.273); catalogued as COSV55174299; called by muse, mutect2, varscan2
- CYP2J2 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 198/417 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs888270915, COSV64605835; called by muse, mutect2, varscan2
- FBXO7 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56678642; called by muse, mutect2, varscan2
- FCAMR | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 187/240 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942157612, COSV100249171; called by muse, mutect2, varscan2
- FLG | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 232/337 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs201066653; called by mutect2, varscan2
- FREM3 | c.5944G>A p.V1982I | Missense Mutation (SNP) | VAF 91/187 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as rs954270962, COSV61682060; called by muse, mutect2, varscan2
- GREB1 | c.5273G>A p.R1758Q | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs760722393; called by muse, mutect2, varscan2
- GRIN2A | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs367543123, COSV58021077; ClinVar: not provided; called by muse, mutect2, varscan2
- GRM4 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 241/360 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs747427620, COSV65213574; called by muse, mutect2, varscan2
- HERC1 | c.7309G>A p.A2437T | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs367997811; called by muse, mutect2, varscan2
- HUNK | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 206/405 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs754441068, COSV54226102; called by muse, mutect2, varscan2
- IGHV3-13 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.48); catalogued as rs1555437235; called by muse, mutect2, varscan2
- KRTAP4-7 | c.131G>C p.C44S | Missense Mutation (SNP) | VAF 568/682 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV66951930; called by muse, varscan2
- LRRC9 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1009522324; called by muse, mutect2, varscan2
- MAD1L1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 290/697 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs756134237; called by muse, varscan2
- MC4R | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs758426526, CM035970, COSV55351515; called by muse, mutect2, varscan2
- NFATC2 | c.1791C>G p.I597M | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65356363; called by muse, mutect2, varscan2
- NOS1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 234/386 reads (61%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1051778934, COSV57623027; called by muse, mutect2, varscan2
- NR0B1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 109/470 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.628); catalogued as rs104894888, CM940013; called by muse, mutect2, varscan2
- NRXN3 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV73587775; called by muse, mutect2, varscan2
- OR2A14 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 170/436 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs761628504, COSV101376503; called by muse, mutect2, varscan2
- PARVB | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1223689233; called by muse, mutect2, varscan2
- PCDHGB2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 221/350 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV53986548; called by muse, mutect2, varscan2
- PKN3 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 75/440 reads (17%) | catalogued as rs771744489; called by muse, mutect2, varscan2
- PLEKHG4B | c.1394C>T p.A465V (on ENST00000283426; = p.A821V on NM_052909.5) | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as rs376874976; called by muse, mutect2, varscan2
- PNMA6F | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 259/521 reads (50%) | SIFT tolerated (0.44); catalogued as rs193001516; called by muse, mutect2, varscan2
- RAB40AL | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 155/382 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.92); catalogued as rs747476866; called by muse, mutect2, varscan2
- RALYL | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 68/443 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72818856; called by muse, mutect2, varscan2
- RTKN | c.1123C>G p.L375V (on ENST00000272430 / NM_001015055.2; = p.L362V on NM_033046.2) | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs754600529; called by muse, mutect2, varscan2
- SDE2 | c.952del p.E318Rfs*13 | Frame Shift Del (DEL) | VAF 103/603 reads (17%) | catalogued as COSV55251262; called by mutect2, pindel, varscan2
- SEMA3E | c.336G>A p.A112= | Splice Region (SNP) | VAF 50/270 reads (19%) | catalogued as rs770979660, COSV57097655; called by muse, mutect2, varscan2
- SGCZ | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 174/357 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372855106; called by muse, varscan2
- SLC12A3 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs387907472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9A2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.124); catalogued as COSV52133460, COSV52134343; called by muse, mutect2
- SNAP91 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as COSV52130428; called by muse, mutect2, varscan2
- SVIL | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs373559551; called by muse, mutect2, varscan2
- TEKT4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 163/415 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs782314314, COSV54623601; called by muse, mutect2, varscan2
- TESC | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 164/494 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as rs1294729983; called by muse, mutect2, varscan2
- TXLNB | c.793A>G p.S265G | Missense Mutation (SNP) | VAF 216/328 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs375239112; called by muse, mutect2, varscan2
- UBASH3A | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs749296137; called by muse, mutect2, varscan2
- VPS13A | c.8756G>C p.G2919A | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487147914; called by muse, mutect2, varscan2
- VSTM2B | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs761971447, COSV100139189, COSV59259691; called by muse, mutect2, varscan2
- VSX2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 122/441 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1205109093; called by muse, mutect2, varscan2
- WDR70 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 40/188 reads (21%) | catalogued as rs916615406; called by muse, mutect2, varscan2
- ABCA9 | c.3377C>G p.S1126* | Nonsense Mutation (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- ABCB5 | c.1932C>G p.N644K (on ENST00000404938 / NM_001163941.2; = p.N199K on NM_178559.6) | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANXA8L1 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 225/491 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ATF7 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF7 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCL11A | c.524del p.P175Rfs*9 (on ENST00000335712 / NM_001365609.1; = p.P209Rfs*9 on NM_018014.4) | Frame Shift Del (DEL) | VAF 73/316 reads (23%) | called by mutect2, pindel, varscan2
- BICDL2 | c.952_956del p.T318Dfs*50 | Frame Shift Del (DEL) | VAF 90/394 reads (23%) | called by mutect2, pindel, varscan2
- C6 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC112 | c.55_58del p.E19Ifs*4 | Frame Shift Del (DEL) | VAF 19/190 reads (10%) | called by mutect2, pindel
- CDH6 | c.1200_1202del p.T401del | In Frame Del (DEL) | VAF 127/351 reads (36%) | called by pindel, varscan2
- CDK5RAP2 | c.3127C>T p.Q1043* | Nonsense Mutation (SNP) | VAF 76/265 reads (29%) | called by muse, mutect2, varscan2
- CEACAM5 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 187/539 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- CENPE | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CERS6 | c.770_787del p.Q257_L262del | In Frame Del (DEL) | VAF 53/280 reads (19%) | called by mutect2, pindel, varscan2
- CFAP57 | c.888_889del p.C297Ffs*11 | Frame Shift Del (DEL) | VAF 111/497 reads (22%) | called by mutect2, pindel, varscan2
- CMTM7 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 189/507 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.1678A>T p.N560Y | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FFAR3 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 91/577 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- FRMD5 | c.417C>A p.Y139* | Nonsense Mutation (SNP) | VAF 66/113 reads (58%) | called by muse, mutect2, varscan2
- GEMIN5 | c.376G>C p.V126L | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GSPT1 | c.1168G>A p.G390R (on ENST00000420576 / NM_001130007.2; = p.G528R on NM_002094.4) | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HAUS6 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRAK4 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 54/304 reads (18%) | called by muse, mutect2, varscan2
- KCTD3 | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 224/397 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KLF10 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- KLK2 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 254/680 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KNL1 | c.2412_2415del p.E804Dfs*9 (on ENST00000346991 / NM_170589.5; = p.E778Dfs*9 on NM_144508.5) | Frame Shift Del (DEL) | VAF 101/243 reads (42%) | called by mutect2, pindel, varscan2
- LIMA1 | c.1984A>C p.T662P | Missense Mutation (SNP) | VAF 263/461 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP6 | c.1567del p.S523Qfs*37 | Frame Shift Del (DEL) | VAF 32/231 reads (14%) | called by mutect2, pindel, varscan2
- MCM4 | c.1352A>C p.E451A | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.058); called by muse, mutect2
- MEF2A | c.1008_1009+33del p.X336_splice (on ENST00000557942 / NM_001319206.2; = p.X330_splice on NM_005587.4 and 8 other RefSeq transcripts) | Splice Site (DEL) | VAF 68/155 reads (44%) | called by mutect2, pindel, varscan2
- MSGN1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MTMR14 | c.535del p.E179Rfs*36 | Frame Shift Del (DEL) | VAF 81/328 reads (25%) | called by mutect2, pindel, varscan2
- NRXN3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 121/344 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR4D1 | c.670A>T p.M224L | Missense Mutation (SNP) | VAF 381/382 reads (100%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR51A2 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 139/431 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, varscan2
- OXCT2 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 60/581 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- PGM2 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 140/220 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PID1 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 43/498 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.946); called by muse, mutect2
- PKHD1L1 | c.12380T>A p.L4127H | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- PLEKHG2 | c.754_763del p.K252Rfs*19 | Frame Shift Del (DEL) | VAF 62/350 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF12 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 147/343 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPN21 | c.1988_1989del p.E663Gfs*35 | Frame Shift Del (DEL) | VAF 140/564 reads (25%) | called by pindel, varscan2
- RNGTT | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ROR2 | c.1024del p.L342Cfs*103 | Frame Shift Del (DEL) | VAF 130/471 reads (28%) | called by mutect2, pindel, varscan2
- SEMG2 | c.775_793del p.E259Rfs*66 | Frame Shift Del (DEL) | VAF 111/411 reads (27%) | called by mutect2, pindel, varscan2
- SKIL | c.38del p.G13Afs*6 | Frame Shift Del (DEL) | VAF 50/320 reads (16%) | called by mutect2, pindel, varscan2
- SMC1B | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SUPT16H | c.1642_1644del p.P548del | In Frame Del (DEL) | VAF 57/245 reads (23%) | called by mutect2, pindel, varscan2
- TCEAL1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 145/331 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEANC2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TERB1 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TERF2 | c.107del p.G36Afs*123 | Frame Shift Del (DEL) | VAF 160/597 reads (27%) | called by mutect2, pindel, varscan2
- TGFBI | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 118/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TP53I3 | c.582del p.E195Rfs*8 | Frame Shift Del (DEL) | VAF 53/251 reads (21%) | called by mutect2, pindel, varscan2
- TRIM64B | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- TRMT11 | c.361_362del p.Q121Rfs*11 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | called by pindel, varscan2
- TTC30B | c.765_769del p.N255Kfs*12 | Frame Shift Del (DEL) | VAF 47/436 reads (11%) | called by mutect2, pindel, varscan2
- TTYH3 | c.1040del p.Q347Rfs*4 | Frame Shift Del (DEL) | VAF 80/457 reads (18%) | called by mutect2, pindel, varscan2
- TWF1 | c.145T>A p.W49R | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC13A | c.270G>A p.E90= | Splice Region (SNP) | VAF 150/375 reads (40%) | called by muse, mutect2, varscan2
- URGCP | c.2733G>T p.R911S (on ENST00000453200 / NM_001077663.3; = p.R902S on NM_017920.4) | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USP26 | c.2445A>T p.R815S | Missense Mutation (SNP) | VAF 150/350 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF721 | c.2671A>G p.R891G (on ENST00000338977; = p.R903G on NM_133474.4) | Missense Mutation (SNP) | VAF 159/237 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACTN4 | c.633G>A p.E211= | Silent (SNP) | VAF 169/468 reads (36%) | called by muse, mutect2, varscan2
- BDKRB2 | c.693G>T p.V231= | Silent (SNP) | VAF 266/416 reads (64%) | called by muse, mutect2, varscan2
- CCDC120 | c.381G>A p.A127= | Silent (SNP) | VAF 194/436 reads (44%) | called by muse, mutect2, varscan2
- GRIK1 | c.1713C>G p.L571= | Silent (SNP) | VAF 228/469 reads (49%) | called by muse, mutect2, varscan2
- HCN3 | c.429C>T p.L143= | Silent (SNP) | VAF 43/720 reads (6%) | catalogued as rs1193260764; called by muse, mutect2
- HSPH1 | c.1602C>T p.D534= | Silent (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- HYDIN | c.11322G>A p.T3774= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as rs529795965; called by muse, varscan2
- KMT2D | c.14226C>T p.P4742= | Silent (SNP) | VAF 178/408 reads (44%) | catalogued as rs1229281996; called by muse, mutect2, varscan2
- LANCL3 | c.1182C>T p.G394= | Silent (SNP) | VAF 35/359 reads (10%) | called by muse, mutect2, varscan2
- LYPD5 | c.384G>A p.P128= (on ENST00000377950 / NM_001031749.3; = p.P85= on NM_182573.2) | Silent (SNP) | VAF 86/467 reads (18%) | catalogued as rs371523113; called by muse, mutect2, varscan2
- MAP3K19 | c.3822C>T p.A1274= | Silent (SNP) | VAF 115/214 reads (54%) | catalogued as rs777421257, COSV100208380; called by muse, mutect2, varscan2
- MATN2 | c.2868A>G p.R956= | Silent (SNP) | VAF 123/265 reads (46%) | called by muse, mutect2, varscan2
- MYBPC1 | c.753C>T p.S251= (on ENST00000550270 / NM_206820.2; = p.S276= on NM_002465.4) | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs753935679, COSV100637708; called by muse, mutect2, varscan2
- NAIF1 | c.945G>A p.Q315= | Silent (SNP) | VAF 98/326 reads (30%) | called by muse, varscan2
- NKX6-3 | c.60G>A p.P20= | Silent (SNP) | VAF 169/383 reads (44%) | catalogued as rs1315904214; called by muse, mutect2, varscan2
- NLRP12 | c.2838G>A p.L946= | Silent (SNP) | VAF 232/510 reads (45%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6303C>A p.P2101= | Silent (SNP) | VAF 176/914 reads (19%) | called by muse, mutect2, varscan2
- PCSK4 | c.711C>T p.T237= | Silent (SNP) | VAF 117/557 reads (21%) | catalogued as rs146245320; called by muse, mutect2, varscan2
- SATB1 | c.81A>G p.P27= | Silent (SNP) | VAF 243/455 reads (53%) | catalogued as rs748444125, COSV58667363; called by muse, mutect2, varscan2
- SLC22A15 | c.681A>G p.L227= | Silent (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- SNAP91 | c.1218A>C p.P406= | Silent (SNP) | VAF 105/332 reads (32%) | called by muse, mutect2, varscan2
- TJP3 | c.1275G>A p.Q425= | Silent (SNP) | VAF 105/479 reads (22%) | called by muse, mutect2, varscan2
- TMEM132C | c.3174C>A p.T1058= | Silent (SNP) | VAF 230/567 reads (41%) | called by muse, mutect2, varscan2
- TNRC6A | c.1428T>A p.P476= | Silent (SNP) | VAF 97/275 reads (35%) | called by muse, mutect2, varscan2
- TRIL | c.2061C>T p.A687= | Silent (SNP) | VAF 59/821 reads (7%) | catalogued as rs977373367; called by muse, mutect2
- UGT2B4 | c.303A>G p.P101= | Silent (SNP) | VAF 80/255 reads (31%) | called by muse, mutect2, varscan2
- UROC1 | c.1806C>T p.N602= | Silent (SNP) | VAF 215/279 reads (77%) | catalogued as rs138856930, COSV52034016; called by muse, mutect2, varscan2
- CCDC40 | c.2832+406C>T | Intron (SNP) | VAF 141/1019 reads (14%) | catalogued as rs762739933; called by muse, varscan2
- FRAS1 | c.5856+16G>A | Intron (SNP) | VAF 202/324 reads (62%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1298+37del | Intron (DEL) | VAF 212/467 reads (45%) | called by mutect2, pindel, varscan2
